Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A67Y, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A67Y-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 1
SEX: F

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Patient with history of pheochromocytoma. Clinical Diagnosis:
Pheochromocytoma. Operative Procedure/Tissue Submitted: Right posterior
approach. Retroperitoneal laparoscopic adrenalectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "Right adrenal gland." Received in formalin in a medium container is a
27.0 gram, 6.5 x 4.7 x 2.0 cm adrenal gland remarkable for a circumscribed and
encapsulated 4.5 x 4.0 x 2.0 cm nodule. External surface is inked blue.
Sectioning reveals that the mass has red-brown cut surface, with areas of
yellow-tan, and possible hemorrhage. The possible capsule is less than 0.1 cm
in thickness. The adjacent adrenal gland shows thin, yellow-orange renal
cortex and thin, red-brown medulla. Representative sections of encapsulated
mass to adjacent normal adrenal parenchyma and capsule submitted in cassette
1A - F.

PROCEDURE: SPDX

VERIFIED BY:

1. Right adrenal gland, resection: Pheochromocytoma (4.5 cm), completely
excised.

I, , the signing staff pathologist, have personally
examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

HP/PA Discrepancy		///

lw 4/22/13
1113

Source: NCI Genomic Data Commons file 1df78744-1ec2-44ee-91d6-866c72db8781 (TCGA-RW-A67Y.460F6959-2CDE-47DC-8EBD-A24EB46E838B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).